Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5527, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5527-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a serum PSA value of 7.7 ng/ml. The patient also had a prostate needle biopsy on [REDACTED] this biopsy revealed prostatic adenocarcinoma, Gleason score 4+4 = 8, involving the right side of the prostate, total linear extent 1.2 cm. The patient also has a history of surgery to remove a cyst from his jaw, bilateral inguinal hernia repairs, amputation of two toes on his right foot, umbilical hernia repair, left rotator cuff surgery, hypertension and hypercholesterolemia.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy and bilateral pelvic lymph node dissection.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN TWO LYMPH NODES (0/2).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN SEVEN LYMPH NODES (0/7).

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE WITH FOCAL SIGNET RING FEATURES, GLEASON SCORE 4 + 3 = 7 WITH TERTIARY GLEASON PATTERN 5 COMPONENT. GLEASON PATTERNS 4/5 COMPONENTS COMPRISE APPROXIMATELY 60% OF THE SAMPLED TUMOR VOLUME (See comment).
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST HISTOLOGIC NODULAR DIAMETER OF 2.1 cm.
- C. CARCINOMA INVOLVES 10-15% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. FOCAL CARCINOMATOUS EXTRACAPSULAR EXTENSION IS PRESENT IN THE RIGHT POSTERIOR APEX AND RIGHT POSTERIOR MID PROSTATE (Slides 3U, 3V).
- E. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- F. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. BILATERAL SEMINAL VESICLES AND BILATERAL DISTAL VASA DEFERENTIA ARE BENIGN.
- H. ALL EXAMINED ASSESSABLE SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA (See comment).
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. TNM PATHOLOGIC STAGE: pT3a N0 MX.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. BACKGROUND PROSTATE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION (See synoptic).

COMMENT:

Part 3: immunohistochemical stains and deeper levels are obtained on slide 3R to evaluate the carcinoma which appears close to one edge of the tissue representing the left anterior apex capsule. Additional levels are examined, and suggest ink displaced onto a cut surface of prostate tissue, rather than neoplastic glands present at the surgical resection margin.

A PIN4 immunostain (p63, cytokeratin 903, P504S), p63, and racemase support the diagnosis of carcinoma by demonstrating a lack of basal cells and positive cytoplasmic staining with P504S.

A section in slide 3M is suboptimally oriented in the tissue block precluding capsular and margin assessment in this section.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 7.7
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS Signet ring adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	74.80gm
TUMOR SIZE:	Maximum dimension: 2.1 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Focal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	9
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated
Comment:	Tertiary Gleason pattern 5 carcinoma component is also present

TCGA - EJ - 5527

Source: NCI Genomic Data Commons file 84b12d46-764d-4dc2-bfb8-ef04e643540d (TCGA-EJ-5527.B4C74B9E-B639-4488-AEF1-8BF008324F73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).